Surgical pathology report (de-identified scan), TCGA case TCGA-G8-6914, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Roswell Park, specimen TCGA-G8-6914-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

FS1 LEFT CERVICAL LEVEL 5 L.N.

CLINICAL HISTORY:

FNA - malignant histology

FINAL DIAGNOSIS:

LYMPH NODE, LEFT CERVICAL, LEVEL 5, biopsy:
MALIGNANT LYMPHOMA, DIFFUSE, LARGE CELL TYPE (IWF G1),
B-CELL PHENOTYPE. See note.

DIAGNOSIS COMMENT:

A preliminary flow cytometric report indicates that the lymphoma cells are positive for CD19, CD20 and CD22, with a Kappa/Lambda ratio of 59.9/0.23.

FROZEN SECTION DIAGNOSIS:

FS1: Malignant lymphoma by Dr.
Comment: Seen in consultation with Dr. who concurs with the diagnosis.
Dx called to Dr. on

GROSS DESCRIPTION:

FS1 LEFT CERVICAL LEVEL 5 LYMPH NODE:
Received are two tannish nodular masses measuring 3x2x2 and 4x3x2 cm. The cut surface reveals a tannish fleshy and faintly lobulated surface. Samples were taken for cytogenetic tissue procurement and frozen tissue for IHC. The remaining portions were submitted in B5 and formalin. Representative sections are submitted as follows: FS1-frozen section, F1 and F2-tissue fixed in formalin, B51 and B52-tissue fixed in B5 fixative.

Date of surgery:

[page 2 of 2]
SPECIMENS:

BM BX RA
BM BX LA

FINAL DIAGNOSIS:

BONE MARROW, right and left iliac crest biopsies, sections,
imprints and smears: ORDERLY HEMOPOIESIS. Negative for lymphoma

DIAGNOSIS COMMENT:

[BBone Marrow 1: Asp & Bx (No cytochem)]b

Pt. Data: Hgb 14.6 WBC 5.38 Plat. 273.0

I. [UAspirate - Differential]u(%):

Cells Counted 500 Cellularity estimate 2+ M:E 1.8/1

Megakaryocytes: Dysplasia: Grade 0 Quantity: Normal

[UMyeloid cells]u[u] Monos/Lymphs[u] [UErythroid cells/Other]u
Dysplasia Grade 0 Dysplasia Grade 0

2.6 myeloblasts NG monoblasts 0.2 pronorm.
1.6 promyelocytes NG promonocytes 33.4 normoblasts
12.0 myelocytes 0.8 monocytes NG sideroblasts *
13.4 metamyelocytes 4.2 lymphocytes NG ring siderobl.**
13.0 bands/stabs NG lymphoblasts 0.2 plasma cells
15.2 segs NG abnormal lymphs NG histiocytes
3.4 eosinophilic NG unclass. blasts NG other _____
NG basophilic 62.0 TOTAL myeloid & mono

*: as % of normoblasts; **: as % of all nucleated cells

Comment on Diff: Normal hematopoiesis.

II. [U Biopsy data]u:

1. Cellularity: 0-50%, average 35%
2. Myeloid/erythroid ratio: 2/1
3. Myeloid series: Dysplasia: Grade 0 Quantity: Adequate
4. Erythroid series: Dysplasia: Grade 0 Quantity: Adequate
5. Megakaryocytes: Dysplasia: Grade 0 Quantity: Rare
0-4/hpf
6. Iron stores: NG
7. Abnormal infiltrate: None
8. Other:
9. Comparison to Previous Bx: N/A

GROSS DESCRIPTION:

1. BM BX RA
Received in B5 in container labelled with patient name is a brown tan fragment of bone measuring 0.9x0.2x0.2cm.
Submitted in toto.
2. BM BX LA
Received in B5 in container labelled with patient name are two brown tan fragments of bone aggregating to a length of 1.0cm. Submitted in toto.

Source: NCI Genomic Data Commons file 86e7d98a-159f-47c6-bf1d-e071e0678820 (TCGA-G8-6914.DB52DBF0-0988-4C64-ABC5-6C38FE32DA83.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).